Somatic mutation profile of tumor specimen 0DEHPR from CCDI case PBBPIH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Atypical teratoid/rhabdoid tumor; Tissue or organ of origin: Brain stem; Age at diagnosis: 6.6 years (2,408 days).
Specimen 0DEHPR: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fcea82e5-83e8-45b8-a1e9-b58b8b76f154.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DEHN7 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bb75c89b-8299-49ec-a4ce-93544d196774

The open-access MAF lists 19 somatic variants for this specimen: 12 protein-altering or splice-affecting, 1 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Intron 5, Silent 1, RNA 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNB4 | c.844C>T p.R282C | Missense Mutation (SNP) | VAF 34/577 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs762399717, COSV52391696; called by muse, mutect2
- CDH4 | c.560C>T p.P187L | Missense Mutation (SNP) | VAF 32/494 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.693); catalogued as COSV100848436; called by muse, mutect2
- FANCA | c.4285G>A p.D1429N | Missense Mutation (SNP) | VAF 18/221 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748856769, COSV57073451; called by muse, mutect2
- KDR | c.1862C>A p.T621K | Missense Mutation (SNP) | VAF 55/912 reads (6%) | SIFT tolerated (0.86); PolyPhen possibly damaging (0.742); catalogued as rs1290988531; called by muse, mutect2
- MRPL55 | c.287G>A p.R96H | Missense Mutation (SNP) | VAF 91/525 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs201322831; called by muse, mutect2, varscan2
- MTUS2 | c.869C>A p.S290* | Nonsense Mutation (SNP) | VAF 12/355 reads (3%) | catalogued as COSV70912573; called by muse, mutect2
- ACIN1 | c.3179A>G p.E1060G | Missense Mutation (SNP) | VAF 26/540 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.945); called by muse, mutect2
- CROCC | c.2183G>A p.R728K | Missense Mutation (SNP) | VAF 36/602 reads (6%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.543); called by muse, mutect2
- DMRT3 | c.791C>T p.P264L | Missense Mutation (SNP) | VAF 53/339 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SHOC2 | c.1705A>G p.I569V | Missense Mutation (SNP) | VAF 103/678 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- TCF7L2 | c.16G>C p.G6R | Missense Mutation (SNP) | VAF 127/349 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- WIF1 | c.839A>G p.Q280R | Missense Mutation (SNP) | VAF 53/950 reads (6%) | SIFT tolerated (0.46); PolyPhen benign (0.219); called by muse, mutect2
- ARPC2 | c.738G>A p.T246= | Silent (SNP) | VAF 31/533 reads (6%) | catalogued as rs748832042; called by muse, mutect2
- ACD | c.671+10G>A | Intron (SNP) | VAF 98/249 reads (39%) | called by muse, mutect2, varscan2
- AL359741.1 | n.215G>A | RNA (SNP) | VAF 22/224 reads (10%) | called by muse, mutect2
- LTC4S | c.59-12del | Intron (DEL) | VAF 10/60 reads (17%) | called by mutect2, varscan2
- PAQR6 | c.180-13G>A | Intron (SNP) | VAF 14/192 reads (7%) | catalogued as rs1388610375; called by muse, mutect2
- RACK1 | c.281+87_281+88dup | Intron (INS) | VAF 17/81 reads (21%) | called by mutect2, varscan2
- SNAP23 | c.99+95A>G | Intron (SNP) | VAF 10/88 reads (11%) | called by muse, mutect2
